Somatic mutation profile of tumor specimen 0DDA7C from CCDI case PBBNJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.5 years (4,579 days).
Specimen 0DDA7C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed39d50f-22d4-40f2-9622-ff27c362a46a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDA72 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d6f3a56-31dd-493d-bcd7-c87dd7a242d6

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Intron 3, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 240/504 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 258/663 reads (39%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 315/801 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CNNM1 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 221/512 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs142775718; called by muse, mutect2, varscan2
- FCAR | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs140716224; called by muse, mutect2, varscan2
- NEU1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 136/178 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs570314472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1I3 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 173/441 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs368339212; called by muse, mutect2, varscan2
- OR4E2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 148/334 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376724041; called by muse, mutect2, varscan2
- SUSD1 | c.1782dup p.T595Yfs*41 | Frame Shift Ins (INS) | VAF 278/641 reads (43%) | catalogued as rs1564257544; called by mutect2, varscan2
- TRIM22 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1407087650; called by muse, mutect2
- UCKL1 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs370751969; called by muse, mutect2, varscan2
- ZNF768 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.078); catalogued as rs1306866801; called by muse, mutect2, varscan2
- C22orf31 | c.58T>A p.S20T | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- COPS2 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 217/549 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP19A1 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 90/872 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- FBXW7 | c.2072G>A p.G691E (on ENST00000281708 / NM_001349798.2; = p.G611E on NM_018315.5) | Missense Mutation (SNP) | VAF 304/687 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FRMD3 | c.522T>G p.S174R | Missense Mutation (SNP) | VAF 325/791 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MOCS3 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PCDHB11 | c.2210T>C p.V737A | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRRG4 | c.656A>T p.K219I | Missense Mutation (SNP) | VAF 64/796 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- RIPOR2 | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 204/266 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SERPINI2 | c.512T>A p.F171Y | Missense Mutation (SNP) | VAF 277/657 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLITRK4 | c.957A>C p.K319N | Missense Mutation (SNP) | VAF 266/632 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- URB2 | c.1427T>A p.V476E | Missense Mutation (SNP) | VAF 135/330 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK9 | c.5268G>C p.L1756= (on ENST00000376460 / NM_001366676.2; = p.L1757= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/349 reads (48%) | called by muse, mutect2, varscan2
- KLHL30 | c.552C>T p.A184= | Silent (SNP) | VAF 14/466 reads (3%) | catalogued as rs1026662522; called by muse, mutect2
- OR5T3 | c.288T>C p.N96= | Silent (SNP) | VAF 36/503 reads (7%) | catalogued as COSV57382043; called by muse, mutect2
- PHB | c.786G>A p.A262= | Silent (SNP) | VAF 126/280 reads (45%) | catalogued as rs566049860, COSV55931865; called by muse, mutect2, varscan2
- RXRA | c.369C>T p.P123= | Silent (SNP) | VAF 132/294 reads (45%) | catalogued as rs1329733740; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 20/597 reads (3%) | called by muse, mutect2
- LRIT3 | c.117-19G>T | Intron (SNP) | VAF 136/305 reads (45%) | called by muse, mutect2, varscan2
- THEG | c.432-97G>C | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- UTP25 | c.1781+36C>A | Intron (SNP) | VAF 87/168 reads (52%) | called by muse, mutect2, varscan2
